Gene-level copy-number profile of tumor specimen TCGA-SC-A6LN-01A from TCGA case TCGA-SC-A6LN, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 76.4 years (27,917 days).
Specimen TCGA-SC-A6LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.98306314-d1dc-44da-b5c4-d4d16f8053a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SC-A6LN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06d5b05d-3bd5-40ef-84b9-95343856ebf2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 21,432; copy number 2: 34,024; copy number 3: 4,299; copy number 4: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SC-A6LN-01A-11D-A34B-01): tumor purity 0.57, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:147,585,438–147,782,775, 2 genes (within-gene range 0–1): JAKMIP2, AC011370.1.
- chr7:86,216,785–86,217,733, 1 gene: SOCS5P1.
- chr9:11,313,397–11,436,244, 1 gene (within-gene range 0–1): AL355672.1.
- chr9:11,618,530–12,058,227, 1 gene (within-gene range 0–1): AL353595.1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr15:27,418,796–27,428,338, 2 genes: AC104002.1, AC104002.2.
- chr22:27,019,369–28,757,515, 37 genes: AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2, AL008638.6, AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.2, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA, MIR5739, RN7SL162P, CHEK2, HSCB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 19,046. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
